Somatic mutation profile of tumor specimen TCGA-DD-AAEI-01A (aliquot TCGA-DD-AAEI-01A-11D-A40R-10) from TCGA case TCGA-DD-AAEI, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 72.5 years (26,465 days).
Specimen TCGA-DD-AAEI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d9dea7d-64cb-4da4-b5bc-1d9d2c7fa42e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAEI-10A (Blood Derived Normal), aliquot TCGA-DD-AAEI-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21024ef0-ea09-4531-b40d-91f06de9205f

The open-access MAF lists 123 somatic variants for this specimen: 101 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 19, Frame Shift Del 6, Splice Region 3, Frame Shift Ins 2, Splice Site 2, Intron 2, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GJA1 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893964, CM030454, COSV99246715; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- AKNA | c.2512G>C p.V838L | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99799360; called by muse, mutect2, varscan2
- ANK3 | c.8207A>T p.E2736V | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as COSV99777641; called by muse, mutect2, varscan2
- ANKRD11 | c.2122A>G p.K708E | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99967938; called by muse, mutect2, varscan2
- APOB | c.8538dup p.G2847Wfs*5 | Frame Shift Ins (INS) | VAF 33/104 reads (32%) | catalogued as rs1370739920; called by mutect2, pindel, varscan2
- ARHGAP25 | c.350-1G>A p.X117_splice (on ENST00000409202 / NM_001007231.3; = p.X110_splice on NM_014882.3) | Splice Site (SNP) | VAF 24/74 reads (32%) | catalogued as COSV99770804; called by muse, mutect2, varscan2
- ARHGAP32 | c.3321C>A p.F1107L (on ENST00000310343 / NM_001378025.1; = p.F758L on NM_014715.4) | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100086517; called by muse, mutect2, varscan2
- ARID2 | c.971T>G p.F324C | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as COSV57600026; called by muse, mutect2
- ARMCX3 | c.978T>G p.N326K | Missense Mutation (SNP) | VAF 132/184 reads (72%) | SIFT tolerated (0.61); PolyPhen benign (0.055); catalogued as COSV100362163; called by muse, mutect2, varscan2
- ASB17 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.489); catalogued as COSV52409893, COSV99407771; called by muse, mutect2, varscan2
- ATM | c.8187A>T p.Q2729H | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs587781946, CM143104, COSV53762213, COSV99586681; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATR | c.5785A>T p.R1929W | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100637531; called by muse, mutect2, varscan2
- BOC | c.1627A>T p.S543C | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99847795; called by muse, mutect2, varscan2
- CACNA1H | c.6001C>T p.R2001W | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.353); catalogued as rs763114755, COSV99326226; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D1 | c.3239C>A p.S1080Y (on ENST00000356253 / NM_001366867.1; = p.S1068Y on NM_000722.4) | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100665204; called by muse, mutect2, varscan2
- CDC14B | c.907T>C p.C303R | Missense Mutation (SNP) | VAF 75/227 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99684993; called by muse, mutect2, varscan2
- CDON | c.3349A>T p.N1117Y | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99700363; called by muse, mutect2, varscan2
- CEP95 | c.2073A>G p.I691M | Missense Mutation (SNP) | VAF 160/438 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.184); catalogued as rs990061896, COSV101616281; called by muse, mutect2, varscan2
- CGB1 | c.272C>G p.P91R | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.133); catalogued as rs1232195649, COSV100031435; called by muse, varscan2
- CHST10 | c.15G>T p.W5C | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV51805453, COSV99958584; called by muse, mutect2, varscan2
- CLSTN2 | c.497A>T p.K166M | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV101515389; called by muse, mutect2, varscan2
- CRHR1 | c.185A>T p.Q62L | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as COSV99523160; called by muse, mutect2, varscan2
- CTNND1 | c.2024G>A p.S675N (on ENST00000399050 / NM_001085458.2; = p.S669N on NM_001331.3) | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV62386347; called by muse, mutect2, varscan2
- CTSW | c.964C>T p.H322Y | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.273); catalogued as rs781782286, COSV100327159; called by muse, mutect2, varscan2
- DIMT1 | c.262C>G p.P88A | Missense Mutation (SNP) | VAF 111/311 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99551011, COSV99551051; called by muse, mutect2, varscan2
- DNAH12 | c.897G>A p.Q299= | Splice Region (SNP) | VAF 23/58 reads (40%) | catalogued as COSV100244269; called by muse, mutect2, varscan2
- DOCK2 | c.1534C>T p.R512* | Nonsense Mutation (SNP) | VAF 32/91 reads (35%) | catalogued as COSV56941078; called by muse, mutect2, varscan2
- DOCK8 | c.5707G>T p.G1903W | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101209761; called by muse, mutect2, varscan2
- DUS3L | c.377C>G p.S126C | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV100287784; called by muse, mutect2, varscan2
- EEF2 | c.989A>C p.K330T | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.673); catalogued as COSV100500516; called by muse, mutect2, varscan2
- EFNB2 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99808482; called by muse, mutect2, varscan2
- EYS | c.1379A>C p.Y460S | Missense Mutation (SNP) | VAF 39/306 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100675464; called by muse, mutect2, varscan2
- FGD2 | c.1473G>T p.R491S | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV99235693; called by muse, mutect2, varscan2
- FGD4 | c.1613A>G p.N538S | Missense Mutation (SNP) | VAF 92/231 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV99846664; called by muse, mutect2, varscan2
- FGF7 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 46/152 reads (30%) | catalogued as COSV99983223; called by muse, mutect2, varscan2
- FOXL1 | c.244C>A p.R82S | Missense Mutation (SNP) | VAF 99/231 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV100206053; called by muse, mutect2, varscan2
- GABRG2 | c.105T>C p.P35= | Splice Region (SNP) | VAF 39/94 reads (41%) | catalogued as COSV100729350; called by muse, mutect2, varscan2
- GCC2 | c.1336T>A p.S446T | Missense Mutation (SNP) | VAF 155/432 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.475); catalogued as COSV100565148; called by muse, mutect2, varscan2
- GDF9 | c.1127G>A p.R376K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.09); catalogued as COSV99736979; called by muse, mutect2, varscan2
- HMCN1 | c.11852C>A p.A3951E | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV54897783, COSV99622321; called by muse, mutect2, varscan2
- HSP90AA1 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 47/130 reads (36%) | PolyPhen probably damaging (0.991); catalogued as COSV100084700; called by muse, mutect2, varscan2
- IFNA2 | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as COSV101206959, COSV66505838; called by muse, mutect2, varscan2
- KAZN | c.784A>T p.M262L | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100747585; called by muse, mutect2, varscan2
- KMT2D | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as rs1324469851, COSV56447212, COSV99976480; called by muse, mutect2, varscan2
- KRT39 | c.914A>T p.Q305L | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100842151; called by muse, mutect2, varscan2
- LARP4B | c.1105A>T p.S369C | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100294941; called by muse, mutect2, varscan2
- LRRTM1 | c.1512C>G p.I504M | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99701538; called by muse, mutect2, varscan2
- MCOLN2 | c.854A>T p.K285I | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV99393516; called by muse, mutect2, varscan2
- MKI67 | c.4458C>G p.H1486Q | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.056); catalogued as COSV100896002; called by muse, mutect2, varscan2
- MORC3 | c.2427G>A p.M809I | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV101264794; called by muse, mutect2, varscan2
- MTCH1 | c.1081A>C p.K361Q (on ENST00000373627 / NM_001271641.1; = p.K344Q on NM_014341.2) | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.276); catalogued as COSV101010143; called by muse, mutect2, varscan2
- MTSS1 | c.1583A>G p.Y528C | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV99412579; called by muse, mutect2, varscan2
- MYBPC2 | c.2452G>T p.G818W | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100731504; called by muse, mutect2, varscan2
- MYH6 | c.3914G>T p.R1305L | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100676151, COSV62449702, COSV62454172; called by muse, mutect2, varscan2
- NEB | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.992); catalogued as COSV99413464; called by muse, mutect2, varscan2
- NIPA1 | c.126C>A p.N42K | Missense Mutation (SNP) | VAF 168/481 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as COSV100507674; called by muse, mutect2, varscan2
- NOTCH1 | c.5990C>T p.T1997M | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1196509879, COSV53040764; called by muse, mutect2, varscan2
- OR56A3 | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.164); catalogued as rs768582191, COSV100289941; called by muse, mutect2, varscan2
- PCDH19 | c.2837T>G p.M946R (on ENST00000373034 / NM_001184880.2; = p.M898R on NM_020766.3) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.043); catalogued as COSV99718764; called by muse, mutect2, varscan2
- PCDHA6 | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1429736622, COSV65348526; called by muse, mutect2, varscan2
- PCSK5 | c.4271C>A p.S1424Y | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs774099593, COSV101377216; called by muse, mutect2, varscan2
- PDE3A | c.2926-1G>A p.X976_splice | Splice Site (SNP) | VAF 28/59 reads (47%) | catalogued as COSV100761486, COSV62970454; called by muse, mutect2, varscan2
- PHACTR1 | c.1706A>T p.E569V | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.119); catalogued as COSV100274893; called by muse, mutect2, varscan2
- PJA2 | c.1915A>T p.S639C | Missense Mutation (SNP) | VAF 143/401 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.928); catalogued as COSV100754247; called by muse, mutect2, varscan2
- PKD1L1 | c.383A>T p.D128V | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.124); catalogued as COSV99217938; called by muse, mutect2, varscan2
- PLIN2 | c.628C>A p.L210M | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99438631; called by muse, mutect2, varscan2
- POTEE | c.2717G>A p.R906Q | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.119); catalogued as rs758912008, COSV100386469; called by muse, mutect2, varscan2
- PPT1 | c.86C>A p.P29Q | Missense Mutation (SNP) | VAF 126/398 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs778256566, COSV100858341; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRRC2C | c.469A>G p.K157E (on ENST00000367742; = p.K155E on NM_015172.4) | Missense Mutation (SNP) | VAF 204/548 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100144465; called by muse, mutect2, varscan2
- RNF151 | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV100364269; called by muse, mutect2, varscan2
- RPS6KA3 | c.1522C>G p.Q508E | Missense Mutation (SNP) | VAF 130/194 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV101084071, COSV65387251; called by muse, mutect2, varscan2
- RRM1 | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as COSV100331188; called by muse, mutect2, varscan2
- SALL1 | c.3323T>A p.V1108D | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV99171466; called by muse, mutect2, varscan2
- SDK1 | c.394T>C p.W132R | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs1247735197, COSV101268564; called by muse, mutect2, varscan2
- SEC23B | c.832del p.E278Rfs*31 | Frame Shift Del (DEL) | VAF 34/120 reads (28%) | catalogued as COSV52721684; called by mutect2, pindel, varscan2
- SH2D3A | c.1697G>A p.G566D | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV99837729; called by muse, mutect2
- SLC2A2 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV100048989; called by muse, mutect2, varscan2
- SLCO5A1 | c.1706T>C p.V569A | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99479162; called by muse, mutect2
- SMARCE1 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 82/140 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV100795929; called by muse, mutect2, varscan2
- SOHLH2 | c.926A>T p.Q309L | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as COSV101157753; called by muse, mutect2, varscan2
- SPAG5 | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100410440; called by muse, mutect2, varscan2
- ST3GAL5 | c.325C>A p.P109T (on ENST00000377332; = p.P149T on NM_003896.4) | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV100088127; called by muse, mutect2, varscan2
- SYNE2 | c.18518A>G p.K6173R | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100646358; called by muse, mutect2, varscan2
- SYNGAP1 | c.2552C>T p.P851L | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV99537664; called by muse, mutect2, varscan2
- SYT8 | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99425263; called by muse, mutect2, varscan2
- TAPT1 | c.1339A>T p.S447C | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100460912; called by muse, mutect2, varscan2
- TCEANC | c.898T>C p.C300R (on ENST00000380600 / NM_001297563.2; = p.C330R on NM_152634.4) | Missense Mutation (SNP) | VAF 96/137 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100124524; called by muse, mutect2, varscan2
- TP53 | c.166del p.E56Kfs*67 | Frame Shift Del (DEL) | VAF 40/75 reads (53%) | catalogued as COSV52771366, COSV52826932, COSV52883452; called by mutect2, pindel, varscan2
- USF3 | c.435A>T p.K145N | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100324589; called by mutect2, varscan2
- USP28 | c.1837T>A p.W613R | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99134374; called by muse, mutect2, varscan2
- USP34 | c.552G>A p.E184= | Splice Region (SNP) | VAF 101/284 reads (36%) | catalogued as COSV101276495; called by muse, mutect2, varscan2
- ZFC3H1 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs561382640, COSV101110268; called by muse, mutect2, varscan2
- ZNF282 | c.199A>C p.M67L | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV100021320; called by muse, mutect2, varscan2
- ZNF285 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs766718884, COSV100449808; called by muse, mutect2, varscan2
- ZNF589 | c.850G>T p.G284C | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100685483; called by muse, mutect2, varscan2
- ZNF589 | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV100685486; called by muse, mutect2, varscan2
- CUX2 | c.306del p.V103Cfs*10 | Frame Shift Del (DEL) | VAF 30/106 reads (28%) | called by mutect2, pindel, varscan2
- MAGI2 | c.3900_3903dup p.A1302Ffs*140 | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | called by mutect2, pindel
- MYH4 | c.2496del p.W833Gfs*2 | Frame Shift Del (DEL) | VAF 40/83 reads (48%) | called by mutect2, pindel, varscan2
- SLC4A3 | c.1188del p.H397Tfs*7 | Frame Shift Del (DEL) | VAF 42/148 reads (28%) | called by mutect2, pindel, varscan2
- ZNF519 | c.1085_1088del p.Y362Lfs*174 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- AHDC1 | c.1929G>A p.P643= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as rs1264963623, COSV99898742; called by muse, mutect2, varscan2
- AKAP11 | c.3807A>T p.T1269= | Silent (SNP) | VAF 51/156 reads (33%) | catalogued as COSV99213367; called by muse, mutect2, varscan2
- CLPTM1L | c.1104G>A p.L368= | Silent (SNP) | VAF 72/205 reads (35%) | catalogued as COSV100306715, COSV100306743; called by muse, mutect2, varscan2
- COL2A1 | c.1767T>A p.P589= | Silent (SNP) | VAF 41/169 reads (24%) | catalogued as COSV100475125; called by muse, mutect2, varscan2
- DNAH10 | c.3762G>A p.Q1254= (on ENST00000409039; = p.Q1193= on NM_207437.3) | Silent (SNP) | VAF 44/270 reads (16%) | catalogued as COSV101291855; called by muse, mutect2, varscan2
- FBLN2 | c.1227G>A p.P409= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as rs748826517, COSV99851153; called by muse, mutect2, varscan2
- IFNA16 | c.156C>T p.C52= | Silent (SNP) | VAF 74/199 reads (37%) | catalogued as COSV101207047; called by muse, mutect2, varscan2
- LRP8 | c.2568C>A p.T856= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV100035893; called by muse, mutect2, varscan2
- NEU4 | c.1113G>A p.P371= (on ENST00000391969 / NM_001167602.3; = p.P383= on NM_080741.4) | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as rs570038056, COSV100371752; called by muse, mutect2, varscan2
- PCDHB13 | c.2058C>T p.L686= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV99506525; called by muse, mutect2, varscan2
- PKD1L2 | c.2673C>T p.G891= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs1162788802, COSV100215949; called by muse, mutect2, varscan2
- PLCB4 | c.2823T>A p.S941= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as COSV99593692; called by muse, mutect2, varscan2
- RETREG2 | c.1138A>C p.R380= | Silent (SNP) | VAF 67/221 reads (30%) | catalogued as COSV99811305, COSV99811423; called by muse, mutect2, varscan2
- SCNN1G | c.624A>C p.S208= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV100263791; called by muse, mutect2, varscan2
- SLC4A10 | c.1161T>A p.I387= (on ENST00000446997 / NM_001354461.2; = p.I357= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 102/296 reads (34%) | catalogued as COSV99761813; called by muse, mutect2, varscan2
- SMCHD1 | c.5091A>T p.S1697= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as COSV99860181; called by muse, mutect2, varscan2
- TECTB | c.459C>T p.S153= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as COSV101027603; called by muse, mutect2, varscan2
- TNRC6A | c.5742C>T p.H1914= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as rs373265827; called by muse, mutect2, varscan2
- TUBGCP2 | c.1965C>T p.L655= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV99427053, COSV99427258; called by muse, mutect2, varscan2
- C6orf223 | n.502_518del | RNA (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- HELT | c.133-111G>A | Intron (SNP) | VAF 50/153 reads (33%) | catalogued as COSV58820646; called by muse, mutect2, varscan2
- NOP56 | c.1160-99G>T | Intron (SNP) | VAF 17/42 reads (40%) | catalogued as COSV100249897; called by muse, mutect2, varscan2
